Somatic mutation profile of tumor specimen TCGA-EE-A2MM-06A (aliquot TCGA-EE-A2MM-06A-11D-A196-08) from TCGA case TCGA-EE-A2MM, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.6 years (26,535 days).
Specimen TCGA-EE-A2MM-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9f1e576-4dd3-4aaf-aca2-88b0ca4100a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2MM-10A (Blood Derived Normal), aliquot TCGA-EE-A2MM-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b01602c-a56e-4583-ab4d-7ca8d4099fa3

The open-access MAF lists 640 somatic variants for this specimen: 419 protein-altering or splice-affecting, 209 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 383, Silent 209, Nonsense Mutation 22, Splice Region 7, RNA 6, Splice Site 5, Intron 4, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL4 | c.32C>T p.S11F | Missense Mutation (SNP) | VAF 27/57 reads (47%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.445); catalogued as rs746887961, COSV66059632; called by muse, mutect2, varscan2
- COL7A1 | c.1637-1G>A p.X546_splice | Splice Site (SNP) | VAF 13/44 reads (30%) | catalogued as rs886058642, CS992999, COSV60400182; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KCNQ5 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59663556; called by mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 135/254 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TACC3 | c.1249C>T p.P417S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.115); catalogued as COSV57603049; called by muse, mutect2, varscan2
- TP53 | c.428T>G p.V143G | Missense Mutation (SNP) | VAF 30/32 reads (94%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555526241, CM1511132, COSV52737174, COSV52760297, COSV52868891; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC8 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 114/255 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV56846607; called by muse, mutect2, varscan2
- AC013489.1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as rs1321259346, COSV51552803; called by muse, mutect2, varscan2
- ACSM2B | c.1403C>T p.S468F | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61657846, COSV61657963; called by muse, mutect2, varscan2
- ACVR1C | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1267033436, COSV54648518; called by mutect2, varscan2
- ADAL | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as COSV67500556; called by muse, mutect2, varscan2
- ADAM2 | c.653C>T p.S218L | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs866239502, COSV55860219; called by mutect2, varscan2
- ADAMTS2 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs867353605, COSV52377133; called by muse, mutect2, varscan2
- ADAMTS20 | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV67136501; called by muse, mutect2, varscan2
- ADCY10 | c.3594G>A p.G1198= | Splice Region (SNP) | VAF 23/76 reads (30%) | catalogued as COSV63243480; called by muse, varscan2
- ADCYAP1R1 | c.1228G>A p.E410K | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58445354; called by muse, mutect2, varscan2
- ADGRD1 | c.2327G>A p.G776D | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55452581; called by muse, mutect2, varscan2
- ADGRV1 | c.2834G>A p.G945E | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs373001982; called by muse, mutect2, varscan2
- ADH1C | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 45/58 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV72463592; called by muse, mutect2, varscan2
- AGAP2 | c.1748C>T p.P583L (on ENST00000547588 / NM_001122772.2; = p.P247L on NM_014770.4) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57730608; called by muse, mutect2, varscan2
- AGBL1 | c.1300C>T p.P434S | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV66857190; called by muse, mutect2, varscan2
- AHI1 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV55632739; called by muse, mutect2
- AHNAK2 | c.13594C>T p.P4532S | Missense Mutation (SNP) | VAF 71/133 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.794); catalogued as COSV60924482; called by muse, mutect2, varscan2
- AMBP | c.524C>T p.P175L | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV54325007; called by muse, mutect2, varscan2
- AMPD3 | c.2182G>A p.D728N (on ENST00000396553 / NM_001025389.2; = p.D737N on NM_000480.3) | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.344); catalogued as rs1483504134, COSV67331917; called by muse, mutect2, varscan2
- ANK3 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 14/15 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55043707; called by muse, mutect2, varscan2
- ANK3 | c.784G>A p.D262N | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as rs868235905, COSV55073278; called by muse, mutect2, varscan2
- AP4E1 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.603); catalogued as COSV55919015; called by muse, mutect2, varscan2
- ARHGAP29 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 81/160 reads (51%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV53115130; called by muse, mutect2, varscan2
- ASCC3 | c.2029C>T p.R677* | Nonsense Mutation (SNP) | VAF 12/30 reads (40%) | catalogued as rs377161298; called by mutect2, varscan2
- ATP13A4 | c.503C>T p.S168L | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as COSV55073050; called by mutect2, varscan2
- ATP1A4 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV63627837; called by muse, mutect2, varscan2
- ATP4A | c.728C>T p.T243M | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142971981; called by mutect2, varscan2
- BARX2 | c.368C>T p.T123M | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.513); catalogued as rs750893952, COSV55649509; called by mutect2, varscan2
- BBOF1 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 39/107 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); catalogued as COSV67455415; called by muse, mutect2, varscan2
- BCAS2 | c.430C>T p.H144Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs753268271, COSV65767663; called by mutect2, varscan2
- BCAS3 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66779302; called by muse, mutect2, varscan2
- BEND6 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV66069843; called by mutect2, varscan2
- BEST3 | c.1166A>T p.H389L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV100437464; called by muse, varscan2
- BMP5 | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs147691986; called by muse, mutect2, varscan2
- BPIFB1 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.28); PolyPhen benign (0.011); catalogued as COSV53607950; called by muse, mutect2, varscan2
- BRCA1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as CD951608, CM087476, COSV58796090; called by muse, mutect2, varscan2
- BSND | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 36/54 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.442); catalogued as COSV64871154; called by muse, mutect2, varscan2
- C1orf210 | c.218G>A p.G73E | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs749422678, COSV70682527; called by muse, mutect2, varscan2
- C6 | c.769G>A p.D257N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as COSV54710078; called by muse, mutect2, varscan2
- C7 | c.923C>T p.S308L | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1244593692, COSV57472254; called by muse, varscan2
- C9orf131 | c.1925G>A p.G642D | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1307567049, COSV56612987; called by muse, varscan2
- C9orf40 | c.544C>T p.Q182* | Nonsense Mutation (SNP) | VAF 50/106 reads (47%) | catalogued as COSV65228673; called by mutect2, varscan2
- CACNA1F | c.4736C>T p.T1579I | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59906218; called by muse, mutect2, varscan2
- CACNA1H | c.6679C>T p.P2227S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.04); catalogued as COSV52356910; called by muse, mutect2, varscan2
- CASP8AP2 | c.3835C>T p.Q1279* | Nonsense Mutation (SNP) | VAF 58/125 reads (46%) | catalogued as COSV52748874; called by muse, mutect2, varscan2
- CATSPER4 | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 57/80 reads (71%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.063); catalogued as COSV58794095; called by muse, mutect2, varscan2
- CATSPERB | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56423395; called by muse, mutect2, varscan2
- CCN6 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as COSV57890055; called by muse, mutect2, varscan2
- CCR8 | c.154G>A p.G52R | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58336789; called by muse, mutect2, varscan2
- CD163L1 | c.2285G>A p.G762E | Missense Mutation (SNP) | VAF 38/50 reads (76%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1023620041, COSV58021583; called by muse, mutect2, varscan2
- CDH10 | c.1069C>T p.P357S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV100051463, COSV52569250; called by muse, mutect2, varscan2
- CDH18 | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56947215; called by muse, mutect2, varscan2
- CDH7 | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.93); catalogued as COSV59891187; called by muse, mutect2
- CDH9 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV50370647, COSV50459979; called by muse, mutect2, varscan2
- CDHR2 | c.1324G>A p.E442K | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs114930966, COSV56141724; called by mutect2, varscan2
- CEMIP | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs368282778; called by mutect2, varscan2
- CFH | c.3320G>A p.G1107E | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.818); catalogued as rs754500480, COSV66406878; called by muse, mutect2, varscan2
- CKAP2L | c.1739C>T p.A580V | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56697464; called by muse, mutect2, varscan2
- CLEC14A | c.1465G>A p.D489N | Missense Mutation (SNP) | VAF 30/58 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV60563748; called by mutect2, varscan2
- CLIP4 | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1193184477, COSV60751174; called by muse, mutect2, varscan2
- CNTN4 | c.976C>T p.H326Y | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.99); PolyPhen possibly damaging (0.761); catalogued as COSV61870011, COSV61878059; called by mutect2, varscan2
- CNTN5 | c.1900G>A p.D634N | Missense Mutation (SNP) | VAF 23/29 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54340550; called by muse, mutect2, varscan2
- COBL | c.3637C>T p.P1213S | Missense Mutation (SNP) | VAF 23/31 reads (74%) | SIFT tolerated (0.53); PolyPhen benign (0.026); catalogued as COSV99470824; called by muse, varscan2
- COBL | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138046636, COSV54341573; called by muse, mutect2, varscan2
- COL12A1 | c.4711G>A p.D1571N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59403457; called by muse, mutect2, varscan2
- COL15A1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV66647944; called by muse, mutect2, varscan2
- COL19A1 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs765873100, COSV59581810; called by muse, mutect2, varscan2
- COL24A1 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 51/112 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755961038, COSV65310873, COSV65313130; called by muse, mutect2, varscan2
- COL4A1 | c.755G>A p.G252E | Missense Mutation (SNP) | VAF 73/210 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.964); catalogued as COSV65429560; called by muse, mutect2, varscan2
- COL5A1 | c.4379C>T p.P1460L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV65673006; called by muse, mutect2, varscan2
- COL5A2 | c.1994G>T p.R665I | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.066); catalogued as COSV66412828, COSV66414248; called by mutect2, varscan2
- CPA3 | c.1250C>T p.S417F | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV56044580; called by muse, mutect2, varscan2
- CPAMD8 | c.5453G>A p.G1818E (on ENST00000651564; = p.G1771E on NM_015692.5) | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.001); catalogued as COSV50186178; called by muse, mutect2, varscan2
- CPNE4 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs753098239, COSV70198062; called by mutect2, varscan2
- CREB5 | c.178C>T p.P60S (on ENST00000357727 / NM_182898.4; = p.P53S on NM_004904.3) | Missense Mutation (SNP) | VAF 113/244 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63220215; called by muse, mutect2, varscan2
- CRTAC1 | c.335G>A p.G112E | Missense Mutation (SNP) | VAF 25/32 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54006875; called by muse, mutect2, varscan2
- CSMD3 | c.2309C>T p.S770F (on ENST00000297405 / NM_001363185.1; = p.S666F on NM_052900.3) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.392); catalogued as COSV52229847, COSV52268030; called by muse, mutect2, varscan2
- CTDP1 | c.2269C>T p.H757Y | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV50007259; called by muse, mutect2, varscan2
- CUL3 | c.85T>C p.Y29H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.935); catalogued as COSV52368285; called by muse, mutect2, varscan2
- CUX2 | c.4279G>A p.A1427T | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs746118929, COSV55634469; called by mutect2, varscan2
- DARS1 | c.86A>T p.Y29F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV51540567; called by muse, mutect2, varscan2
- DDN | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV60293933; called by muse, mutect2, varscan2
- DDOST | c.1214C>T p.S405F (on ENST00000415136; = p.S388F on NM_005216.5) | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.214); catalogued as COSV58632271; called by muse, mutect2, varscan2
- DEFA4 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as COSV52404561; called by muse, mutect2, varscan2
- DENND1A | c.1244T>A p.I415N | Missense Mutation (SNP) | VAF 44/109 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV65330375; called by muse, mutect2, varscan2
- DHX16 | c.2354C>T p.P785L | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV53315596; called by muse, mutect2, varscan2
- DMBT1 | c.5359C>T p.R1787* (on ENST00000338354 / NM_001377530.1; = p.R1030* on NM_004406.3) | Nonsense Mutation (SNP) | VAF 199/225 reads (88%) | catalogued as rs201883302, COSV57540333; called by muse, varscan2
- DNAH3 | c.2265G>A p.M755I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs763895166, COSV54540079; called by muse, mutect2, varscan2
- DNAH5 | c.632C>T p.S211L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs139857637, COSV54254088; ClinVar: uncertain significance; called by mutect2, varscan2
- DNAJA4 | c.184G>A p.D62N (on ENST00000343789; = p.D91N on NM_018602.3) | Missense Mutation (SNP) | VAF 70/162 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as COSV59426638; called by muse, varscan2
- DNAJC16 | c.208T>C p.F70L | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV65449195; called by muse, mutect2, varscan2
- DNMT3B | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV52421570; called by muse, mutect2, varscan2
- DPYD | c.1131G>A p.M377I | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as COSV64609202; called by muse, mutect2, varscan2
- DRD1 | c.742G>A p.G248R | Missense Mutation (SNP) | VAF 68/137 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV67105046; called by muse, mutect2, varscan2
- DSC1 | c.1058C>T p.S353F | Missense Mutation (SNP) | VAF 34/81 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57149352; called by muse, mutect2, varscan2
- DSC3 | c.2281C>T p.Q761* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV64574465; called by muse, varscan2
- DSCAM | c.4541G>A p.R1514K | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1186224886, COSV68030816; called by muse, mutect2, varscan2
- DSG4 | c.2499G>A p.M833I | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV57390418; called by muse, varscan2
- DSP | c.5828G>A p.R1943K | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65791356; called by muse, mutect2
- DSPP | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.316); catalogued as COSV56814175; called by muse, mutect2, varscan2
- ECRG4 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53001560; called by muse, mutect2, varscan2
- ECT2L | c.354G>A p.W118* | Nonsense Mutation (SNP) | VAF 65/123 reads (53%) | catalogued as COSV100872052, COSV62886250; called by muse, mutect2, varscan2
- EFCAB6 | c.3298G>A p.D1100N | Missense Mutation (SNP) | VAF 56/74 reads (76%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1267772930, COSV53068892; called by muse, mutect2, varscan2
- ELOVL4 | c.598G>A p.G200R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100876198, COSV63954250, COSV63954402; called by muse, mutect2, varscan2
- ENOX2 | c.1327C>T p.H443Y (on ENST00000338144 / NM_001382520.1; = p.H414Y on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 110/127 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.127); catalogued as COSV57656091, COSV57659835; called by muse, mutect2, varscan2
- ENPEP | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 13/14 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.311); catalogued as COSV54453849, COSV54455217; called by muse, mutect2, varscan2
- EPB42 | c.2015T>A p.M672K (on ENST00000441366 / NM_001114134.2; = p.M702K on NM_000119.3) | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV55747576; called by muse, mutect2, varscan2
- EPHA6 | c.2212G>A p.E738K (on ENST00000389672 / NM_001080448.3; = p.E130K on NM_173655.4) | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67586812; called by muse, mutect2, varscan2
- ERGIC3 | c.946C>T p.Q316* | Nonsense Mutation (SNP) | VAF 23/52 reads (44%) | catalogued as COSV53415087, COSV53415671; called by muse, mutect2, varscan2
- ESYT3 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 107/264 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.163); catalogued as rs372182457; called by muse, mutect2, varscan2
- F11 | c.851G>A p.R284K | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV53008644; called by muse, varscan2
- F13A1 | c.559C>T p.P187S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV53564226; called by muse, mutect2, varscan2
- F13B | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66375142; called by muse, mutect2, varscan2
- F5 | c.2248G>T p.E750* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as COSV63122287, COSV63126449; called by mutect2, varscan2
- FAM117B | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 126/302 reads (42%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.889); catalogued as COSV57421091; called by mutect2, varscan2
- FAM189B | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV59170618; called by muse, mutect2, varscan2
- FAM193A | c.2575G>A p.E859K | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.325); catalogued as rs970104123, COSV61195975; called by mutect2, varscan2
- FASLG | c.415G>A p.E139K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.027); catalogued as rs745583712, COSV60680660; called by mutect2, varscan2
- FBLN7 | c.767C>T p.P256L | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99734659; called by muse, mutect2, varscan2
- FBN2 | c.1418G>A p.G473E | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs376096770, COSV52535681; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FBN2 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs1301538420, COSV52533846; called by muse, varscan2
- FBN3 | c.7219G>A p.D2407N | Missense Mutation (SNP) | VAF 100/147 reads (68%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.999); catalogued as COSV54468251; called by muse, mutect2, varscan2
- FBXO34 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs149853453; called by mutect2, varscan2
- FER1L6 | c.3341C>T p.S1114L | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs182459401, COSV67548824; called by mutect2, varscan2
- FLG | c.9854G>A p.G3285E | Missense Mutation (SNP) | VAF 122/298 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs749472491, COSV64245750; called by muse, mutect2, varscan2
- FLNB | c.3070C>T p.P1024S | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); catalogued as rs747814541, COSV55889658; called by muse, mutect2, varscan2
- FMN2 | c.3260C>T p.P1087L | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as COSV60444652; called by muse, varscan2
- FMO1 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61447125; called by mutect2, varscan2
- FRAS1 | c.3823C>T p.P1275S | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV53633247; called by muse, mutect2, varscan2
- FSCN1 | c.905C>T p.T302I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV61018400; called by muse, mutect2, varscan2
- GADD45B | c.235C>T p.Q79* | Nonsense Mutation (SNP) | VAF 27/119 reads (23%) | catalogued as COSV53126523; called by muse, mutect2, varscan2
- GCC2 | c.5051G>T p.R1684L | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59176142, COSV59178737; called by muse, mutect2, varscan2
- GDA | c.578G>A p.R193K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.05); catalogued as COSV52996301; called by muse, mutect2, varscan2
- GEMIN4 | c.2710C>T p.P904S | Missense Mutation (SNP) | VAF 24/26 reads (92%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs774075432, COSV56746906; called by muse, mutect2, varscan2
- GIT1 | c.1436C>T p.P479L | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT tolerated (0.45); PolyPhen benign (0.028); catalogued as COSV99837769; called by muse, mutect2, varscan2
- GIT1 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 48/123 reads (39%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99837771; called by muse, mutect2, varscan2
- GPR143 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 39/44 reads (89%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV66632897; called by muse, mutect2, varscan2
- GPR31 | c.91G>A p.G31S | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as COSV100834090; called by muse, mutect2, varscan2
- GRIN2A | c.3466G>A p.E1156K | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV58026228; called by mutect2, varscan2
- GRIN2A | c.2730G>A p.M910I | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV58033008; called by mutect2, varscan2
- GRIN2D | c.1997C>T p.A666V | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54379823; called by muse, mutect2, varscan2
- GRM7 | c.1472G>A p.G491D | Missense Mutation (SNP) | VAF 32/60 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.115); catalogued as COSV63159419; called by muse, mutect2, varscan2
- GRM8 | c.1718C>T p.P573L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV58853689; called by muse, varscan2
- GSDMA | c.571C>T p.H191Y | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.438); catalogued as rs866672492, COSV100053442, COSV100053766, COSV56980106; called by mutect2, varscan2
- HAND2 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV64018742; called by muse, mutect2, varscan2
- HGF | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.718); catalogued as rs758567520, COSV55946847; called by mutect2, varscan2
- HLA-F | c.817G>A p.G273R | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52576002; called by muse, mutect2, varscan2
- HS6ST3 | c.1313G>A p.R438Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs746839989, COSV65009473; called by muse, mutect2, varscan2
- IFNW1 | c.376G>A p.V126I | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as rs1371846732, COSV101207579; called by muse, mutect2, varscan2
- IKZF4 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV56269705; called by mutect2, varscan2
- IMMT | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs1334774616, COSV54488388; called by mutect2, varscan2
- IRAK2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs141630240; called by muse, mutect2, varscan2
- ITGB4 | c.3313C>T p.P1105S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs777991551, COSV52330437; called by muse, mutect2, varscan2
- KAT6A | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 18/27 reads (67%) | catalogued as rs144857451, COSV55910176; called by mutect2, varscan2
- KBTBD12 | c.751C>T p.Q251* | Nonsense Mutation (SNP) | VAF 32/76 reads (42%) | catalogued as COSV59681058; called by mutect2, varscan2
- KCNA4 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 39/125 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.916); catalogued as rs750544378, COSV60254855, COSV60255214; called by muse, mutect2, varscan2
- KCNH1 | c.1786G>A p.E596K (on ENST00000271751 / NM_172362.3; = p.E569K on NM_002238.4) | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.43); PolyPhen benign (0.028); catalogued as rs1486842407, COSV55094930; called by muse, mutect2, varscan2
- KCNT1 | c.2807A>G p.N936S (on ENST00000488444; = p.N955S on NM_020822.3) | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV53707344; called by muse, mutect2, varscan2
- KIAA0100 | c.3689G>T p.R1230L | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.049); catalogued as COSV66492748, COSV66495477; called by mutect2, varscan2
- KIAA0895 | c.202G>A p.E68K (on ENST00000297063 / NM_001100425.2; = p.E17K on NM_015314.3) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51712977; called by muse, mutect2, varscan2
- KIAA1109 | c.12359C>T p.S4120L | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs375630876; called by mutect2, varscan2
- KIAA1755 | c.3215G>A p.G1072E | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.22); PolyPhen benign (0.36); catalogued as COSV54079211; called by muse, mutect2, varscan2
- KIF1B | c.913C>T p.P305S (on ENST00000377086 / NM_001365952.1; = p.P299S on NM_015074.3) | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55813075; called by muse, mutect2, varscan2
- KIF21B | c.4565G>A p.R1522Q (on ENST00000422435 / NM_001252100.2; = p.R1509Q on NM_017596.4) | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs1258132353, COSV59763122; called by mutect2, varscan2
- KIF21B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 21/83 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59763133; called by muse, mutect2, varscan2
- KIF5A | c.369G>A p.M123I | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV54057454; called by muse, mutect2, varscan2
- KIR3DL2 | c.154C>T p.R52C | Missense Mutation (SNP) | VAF 86/183 reads (47%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.95); catalogued as rs769536458, COSV54390813; called by muse, mutect2, varscan2
- KLC4 | c.1511C>T p.T504M | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs745503574, COSV52437413; called by mutect2, varscan2
- KLHL1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.899); catalogued as rs781731142, COSV64766675; called by muse, mutect2, varscan2
- KLHL13 | c.439A>T p.K147* | Nonsense Mutation (SNP) | VAF 59/67 reads (88%) | catalogued as COSV53251330, COSV99451146; called by muse, varscan2
- KLHL22 | c.1090C>T p.R364* | Nonsense Mutation (SNP) | VAF 61/70 reads (87%) | catalogued as rs770146011, COSV61019865; called by muse, mutect2, varscan2
- KREMEN1 | c.1148C>T p.A383V (on ENST00000407188; = p.A385V on NM_032045.5) | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as COSV59914070; called by muse, mutect2, varscan2
- KRT10 | c.134G>A p.G45E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.976); catalogued as COSV54090892; called by muse, mutect2, varscan2
- KRT36 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV60203528; called by muse, varscan2
- KRT5 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV52862527; called by muse, mutect2, varscan2
- LAD1 | c.515G>A p.G172E | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.011); catalogued as rs1425223321, COSV66213027; called by muse, varscan2
- LDHAL6B | c.1067A>G p.K356R | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV55692391; called by muse, mutect2, varscan2
- LFNG | c.511G>A p.A171T (on ENST00000222725 / NM_001040167.2; = p.A42T on NM_002304.2) | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1282612622, COSV56068745, COSV99761596; called by mutect2, varscan2
- LILRA1 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs760878213, COSV52180445; called by muse, mutect2, varscan2
- LRRC3 | c.487G>A p.D163N | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.222); catalogued as COSV52399904; called by muse, mutect2, varscan2
- LRRC4B | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV65350549; called by muse, mutect2, varscan2
- LRRC8A | c.229C>T p.P77S | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV52184381; called by muse, mutect2, varscan2
- LRRC8A | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs201084502, COSV99396151; called by mutect2, varscan2
- LRRIQ1 | c.620G>A p.R207Q | Missense Mutation (SNP) | VAF 90/215 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs371775430; called by muse, mutect2, varscan2
- LRRIQ4 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1246435297, COSV61619890; called by muse, mutect2, varscan2
- MAGEC1 | c.1858G>A p.E620K | Missense Mutation (SNP) | VAF 104/122 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.022); catalogued as rs866448898, COSV53567920; called by muse, mutect2, varscan2
- MAGEE1 | c.2365C>T p.R789C | Missense Mutation (SNP) | VAF 50/60 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs373804803, COSV63909530; called by mutect2, varscan2
- MARCHF1 | c.547G>A p.E183K (on ENST00000274056; = p.E166K on NM_017923.4) | Missense Mutation (SNP) | VAF 20/25 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760767827, COSV56811044; called by muse, mutect2, varscan2
- ME3 | c.1378G>A p.E460K | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.02); catalogued as rs778609173, COSV62773542; called by mutect2, varscan2
- MED18 | c.154C>T p.L52F | Missense Mutation (SNP) | VAF 210/397 reads (53%) | SIFT tolerated (0.59); PolyPhen benign (0.108); catalogued as COSV65790862; called by muse, mutect2, varscan2
- MICB | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.158); catalogued as COSV52857346; called by muse, mutect2, varscan2
- MMS22L | c.2995C>T p.P999S | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as COSV51524530; called by muse, mutect2, varscan2
- MMUT | c.40C>T p.H14Y | Missense Mutation (SNP) | VAF 17/114 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV51279059, COSV99222468; called by mutect2, varscan2
- MPI | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.009); catalogued as rs563261773, COSV60397375; called by muse, mutect2, varscan2
- MROH7 | c.1072G>A p.D358N | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV59875764; called by muse, mutect2, varscan2
- MROH9 | c.163C>T p.P55S | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63012615; called by muse, mutect2, varscan2
- MRPS24 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.202); catalogued as COSV58182624, COSV58183179; called by muse, mutect2, varscan2
- MS4A6E | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 40/80 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752908828, COSV55726872; called by muse, mutect2, varscan2
- MTARC1 | c.813C>T p.S271= | Splice Region (SNP) | VAF 52/92 reads (57%) | catalogued as COSV65056047; called by muse, mutect2, varscan2
- MTCP1 | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 39/47 reads (83%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV62900208; called by muse, varscan2
- MTREX | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV57928763; called by muse, varscan2
- MUC16 | c.26408C>T p.T8803I | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.737); catalogued as COSV67481925; called by muse, mutect2, varscan2
- MUC16 | c.3179G>A p.G1060E | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.877); catalogued as rs148517753, COSV67481929; called by muse, mutect2, varscan2
- MYH1 | c.5716G>A p.E1906K | Missense Mutation (SNP) | VAF 49/103 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.573); catalogued as rs368680249; called by muse, mutect2, varscan2
- MYH3 | c.3102+1G>A p.X1034_splice | Splice Site (SNP) | VAF 29/64 reads (45%) | catalogued as rs756111159, COSV56868281; called by muse, mutect2, varscan2
- MYH8 | c.2866G>A p.D956N | Missense Mutation (SNP) | VAF 164/397 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101238780, COSV67970011; called by muse, mutect2, varscan2
- MYL2 | c.142G>A p.D48N | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs727504405, COSV57406212, COSV57408315; called by mutect2, varscan2
- MYO7A | c.6439G>A p.D2147N | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV60017640; called by muse, mutect2, varscan2
- MYO7B | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs775646954, COSV67350124; called by muse, mutect2, varscan2
- MYO7B | c.1534G>A p.E512K | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371035844; called by mutect2, varscan2
- MYOM2 | c.2291C>T p.P764L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs768172010, COSV100036269; called by muse, mutect2, varscan2
- MYOM3 | c.1723G>A p.V575M | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58398144; called by muse, mutect2, varscan2
- MYT1L | c.1069A>C p.I357L | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV67728285; called by muse, mutect2
- NCKIPSD | c.686G>A p.S229N | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV53662733; called by muse, mutect2, varscan2
- NCR2 | c.225G>A p.M75I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs756839447, COSV66101065; called by muse, mutect2, varscan2
- NDOR1 | c.1237C>T p.P413S (on ENST00000371521 / NM_001144026.3; = p.P406S on NM_014434.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs1188390433, COSV61289402; called by muse, mutect2, varscan2
- NEU4 | c.46G>A p.E16K (on ENST00000391969 / NM_001167602.3; = p.E28K on NM_080741.4) | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV57990140; called by muse, mutect2, varscan2
- NFE2L1 | c.1762G>T p.D588Y | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.08); catalogued as COSV62583663; called by muse, mutect2, varscan2
- NLRP1 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 56/70 reads (80%) | SIFT tolerated (0.59); PolyPhen benign (0.021); catalogued as COSV52561589; called by muse, mutect2, varscan2
- NLRP1 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 111/131 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52573765; called by muse, mutect2, varscan2
- NLRP11 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs141366900; called by mutect2, varscan2
- NOTCH1 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.23); PolyPhen probably damaging (1); catalogued as COSV53076992; called by muse, mutect2, varscan2
- NOVA1 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs1042740142, COSV57478679; called by muse, varscan2
- NPAP1 | c.88C>T p.R30W | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); catalogued as rs558652902, COSV61509774; called by muse, mutect2, varscan2
- NPAP1 | c.695C>T p.S232F | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.087); catalogued as COSV61506067; called by muse, mutect2, varscan2
- NPY1R | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.151); catalogued as COSV56715702; called by mutect2, varscan2
- NPY1R | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 22/24 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as COSV56715714; called by muse, mutect2, varscan2
- NTNG1 | c.815G>A p.G272E | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99634875; called by muse, mutect2, varscan2
- OASL | c.239G>A p.R80K | Missense Mutation (SNP) | VAF 106/270 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV57477278, COSV57479837; called by muse, varscan2
- OBSCN | c.14671G>A p.E4891K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV52808036; called by muse, mutect2, varscan2
- OBSCN | c.15698C>T p.S5233L | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52808057; called by mutect2, varscan2
- OR10C1 | c.194G>A p.R65H (on ENST00000622521; = p.R63H on NM_013941.3) | Missense Mutation (SNP) | VAF 31/299 reads (10%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.828); catalogued as rs779708085, COSV65823122, COSV65823353; called by muse, mutect2, varscan2
- OR10G3 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57810924; called by muse, mutect2, varscan2
- OR10G8 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 21/25 reads (84%) | SIFT tolerated (0.92); PolyPhen benign (0.014); catalogued as COSV70909061; called by muse, mutect2, varscan2
- OR11H1 | c.100C>G p.L34V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.089); catalogued as COSV53271894, COSV99079123; called by mutect2, varscan2
- OR13H1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 23/24 reads (96%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58548160; called by muse, mutect2, varscan2
- OR1S1 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58708038; called by muse, mutect2, varscan2
- OR2A2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs755445994, COSV68871044; called by mutect2, varscan2
- OR2L3 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.076); catalogued as COSV63455909, COSV63455922; called by muse, mutect2, varscan2
- OR4X2 | c.583G>A p.G195R | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56582840; called by muse, varscan2
- OR5AK2 | c.728C>T p.S243F | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58805033; called by muse, mutect2, varscan2
- OR5F1 | c.820G>A p.A274T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.04); catalogued as rs375364958; called by muse, mutect2, varscan2
- OR6B2 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs772067442, COSV53155865; called by muse, mutect2, varscan2
- OR6B3 | c.161C>T p.S54F | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV60115711; called by muse, mutect2, varscan2
- OR6K2 | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 11/28 reads (39%) | catalogued as rs1317450242, COSV62744005; called by muse, mutect2, varscan2
- ORC2 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs184226901, COSV52240589; called by mutect2, varscan2
- OTC | c.384C>T p.A128= | Splice Region (SNP) | VAF 20/21 reads (95%) | catalogued as COSV50003439; called by muse, mutect2, varscan2
- OTOF | c.1505C>T p.S502L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs373654311; called by muse, mutect2, varscan2
- OTUD7B | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.7); PolyPhen benign (0.029); catalogued as COSV100967276; called by muse, mutect2, varscan2
- OTUD7B | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.864); catalogued as COSV100967277; called by muse, mutect2, varscan2
- P3H2 | c.1415C>T p.S472L | Missense Mutation (SNP) | VAF 26/46 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs777721300, COSV60019037; called by mutect2, varscan2
- PAPPA | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV60289183; called by muse, mutect2, varscan2
- PAPPA | c.3143C>T p.S1048F | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs757737311, COSV60289189; called by muse, mutect2, varscan2
- PAPPA2 | c.1118G>A p.G373E | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62783300; called by muse, mutect2, varscan2
- PARN | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 38/86 reads (44%) | catalogued as rs1318821563, COSV58369222; called by muse, mutect2, varscan2
- PARP14 | c.2090T>A p.I697K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV71735322; called by muse, mutect2, varscan2
- PAX8 | c.965C>T p.S322F | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV54509489; called by muse, mutect2
- PCDHB2 | c.1162C>T p.Q388* | Nonsense Mutation (SNP) | VAF 32/62 reads (52%) | catalogued as COSV50606313; called by muse, mutect2, varscan2
- PCDHB7 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50765423; called by muse, mutect2, varscan2
- PCDHB7 | c.2006C>T p.P669L | Missense Mutation (SNP) | VAF 44/242 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV50798901; called by muse, mutect2, varscan2
- PCDHB8 | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs782235899, COSV50769178; called by muse, mutect2
- PCDHGB2 | c.2321T>C p.L774S | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as COSV54001601; called by muse, mutect2, varscan2
- PCLO | c.5963G>A p.G1988E | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV61646298; called by muse, varscan2
- PDE10A | c.1567C>T p.P523S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV63102942; called by muse, varscan2
- PDE10A | c.1315C>T p.R439W | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV63095844; called by muse, mutect2, varscan2
- PDE6D | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs771028029, COSV55020940; called by muse, varscan2
- PDZD2 | c.932C>T p.S311L | Missense Mutation (SNP) | VAF 30/48 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV56867666; called by mutect2, varscan2
- PELP1 | c.2989C>T p.P997S | Missense Mutation (SNP) | VAF 10/10 reads (100%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.351); catalogued as COSV52590760; called by muse, mutect2, varscan2
- PIGO | c.672G>C p.W224C | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53054710; called by muse, mutect2, varscan2
- PIK3C2G | c.3400C>T p.Q1134* (on ENST00000676171; = p.Q1093* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV56823937; called by mutect2, varscan2
- PLCB1 | c.2002G>A p.G668S | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV62061994; called by muse, mutect2, varscan2
- PLEKHG4B | c.658C>T p.R220C (on ENST00000283426; = p.R576C on NM_052909.5) | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149661863, COSV52052280; called by muse, mutect2, varscan2
- PMPCA | c.1445C>T p.S482F | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.125); catalogued as COSV65510501; called by muse, varscan2
- PNISR | c.101G>A p.W34* | Nonsense Mutation (SNP) | VAF 13/25 reads (52%) | catalogued as COSV100984376, COSV65080325; called by muse, mutect2, varscan2
- PNPLA7 | c.118C>A p.R40= | Splice Region (SNP) | VAF 55/125 reads (44%) | catalogued as COSV52994292, COSV53004236; called by muse, mutect2, varscan2
- POGZ | c.2045T>G p.L682W | Missense Mutation (SNP) | VAF 54/357 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55039995; called by muse, mutect2, varscan2
- POU6F2 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV68873678; called by muse, mutect2, varscan2
- PPIL4 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV53568230; called by muse, mutect2, varscan2
- PPP6R3 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as COSV55732969; called by muse, mutect2, varscan2
- PRDM13 | c.188C>T p.S63F | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as rs1324630748, COSV65030497; called by muse, mutect2, varscan2
- PRLR | c.1068C>G p.S356R | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51498670; called by muse, mutect2, varscan2
- PRR30 | c.748C>T p.P250S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53207470; called by muse, mutect2, varscan2
- PSD | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.003); catalogued as rs1202885361, COSV50042451; called by muse, mutect2, varscan2
- PSD4 | c.1211C>T p.P404L | Missense Mutation (SNP) | VAF 62/133 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.131); catalogued as COSV55528840; called by muse, mutect2, varscan2
- PSG4 | c.745T>G p.L249V | Missense Mutation (SNP) | VAF 76/168 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0.12); catalogued as rs770797914, COSV54935795, COSV54938698; called by muse, mutect2, varscan2
- PSG5 | c.974G>A p.G325E | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as COSV61654021; called by muse, varscan2
- PTPN22 | c.2077C>T p.P693S (on ENST00000359785 / NM_001193431.2; = p.P638S on NM_012411.5) | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.117); catalogued as rs751324264, COSV63086042; called by muse, mutect2, varscan2
- PTPRB | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.053); catalogued as COSV51741721; called by mutect2, varscan2
- PTPRT | c.2089C>T p.P697S | Missense Mutation (SNP) | VAF 44/75 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs867675509, COSV62005547; called by muse, mutect2, varscan2
- PXDN | c.395G>A p.G132E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as rs778098532, COSV99411828; called by mutect2, varscan2
- RAB11FIP3 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV51931280; called by muse, mutect2, varscan2
- RALGAPA2 | c.1862A>T p.D621V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52505744; called by muse, mutect2, varscan2
- RASSF5 | c.376G>A p.A126T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.084); catalogued as rs782347381, COSV100794992, COSV62425792; called by mutect2, varscan2
- RAVER1 | c.951C>T p.A317= | Splice Region (SNP) | VAF 14/52 reads (27%) | catalogued as COSV53347535; called by muse, mutect2, varscan2
- RAVER2 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53809581; called by muse, mutect2, varscan2
- RDH16 | c.573-1G>A p.X191_splice | Splice Site (SNP) | VAF 28/76 reads (37%) | catalogued as COSV62458530; called by muse, mutect2, varscan2
- RELN | c.2651G>A p.G884E | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV58987402, COSV59015023; called by muse, mutect2, varscan2
- RGS22 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 50/77 reads (65%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62665503; called by muse, mutect2, varscan2
- RP1 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55109520, COSV55117262; called by mutect2, varscan2
- RP1L1 | c.3809C>T p.A1270V | Missense Mutation (SNP) | VAF 85/143 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as COSV66754584; called by muse, mutect2, varscan2
- RPS6 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 42/122 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as rs1047701964, COSV59548600; called by muse, varscan2
- RRM1 | c.2152G>A p.G718S | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.031); catalogued as COSV56165470; called by muse, mutect2, varscan2
- SCD | c.309G>A p.W103* | Nonsense Mutation (SNP) | VAF 93/101 reads (92%) | catalogued as COSV64853173, COSV64853407; called by muse, mutect2, varscan2
- SCUBE3 | c.2026G>A p.D676N | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as rs1205933947, COSV51459215; called by mutect2, varscan2
- SDAD1 | c.1578C>T p.I526= | Splice Region (SNP) | VAF 127/138 reads (92%) | catalogued as rs1340714146, COSV62402852; called by muse, mutect2, varscan2
- SEC61A1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV99684642; called by muse, mutect2, varscan2
- SERPINA5 | c.520G>A p.D174N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.305); catalogued as COSV61574702; called by mutect2, varscan2
- SERPIND1 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 32/44 reads (73%) | SIFT tolerated (0.05); PolyPhen benign (0.036); catalogued as rs1201336027, COSV53140167; called by muse, mutect2, varscan2
- SERPING1 | c.346C>T p.Q116* | Nonsense Mutation (SNP) | VAF 38/102 reads (37%) | catalogued as CM004900, COSV99557735; called by mutect2, varscan2
- SFI1 | c.325C>T p.P109S | Missense Mutation (SNP) | VAF 36/44 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66292234; called by muse, mutect2, varscan2
- SFXN5 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs749007020, COSV55589287; called by mutect2, varscan2
- SGCD | c.95G>A p.R32Q (on ENST00000435422 / NM_001128209.2; = p.R33Q on NM_000337.5) | Missense Mutation (SNP) | VAF 110/174 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1488623227, COSV61903603; ClinVar: uncertain significance; called by muse, varscan2
- SH2D3A | c.20G>A p.G7E | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV55587509; called by muse, mutect2, varscan2
- SHPK | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.46); PolyPhen benign (0.017); catalogued as rs761164121, COSV56649987; called by mutect2, varscan2
- SIGLEC12 | c.275G>A p.R92Q | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs553546353, COSV52463725; called by muse, mutect2, varscan2
- SIM1 | c.1572G>A p.G524= | Splice Region (SNP) | VAF 20/42 reads (48%) | catalogued as COSV53494920; called by muse, mutect2, varscan2
- SIM1 | c.1283C>T p.S428F | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.839); catalogued as rs1327417874, COSV53494928; called by muse, varscan2
- SIN3A | c.2164G>A p.E722K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100845206, COSV64584282; called by mutect2, varscan2
- SLC15A1 | c.1284G>A p.M428I | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV64732940; called by mutect2, varscan2
- SLC15A2 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55199813; called by mutect2, varscan2
- SLC15A3 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774429665, COSV50015120; called by muse, mutect2, varscan2
- SLC16A14 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV54619530; called by mutect2, varscan2
- SLC24A3 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs765293325, COSV60127509; called by mutect2, varscan2
- SLC26A6 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs771585930, COSV50996203; called by muse, mutect2, varscan2
- SLC30A8 | c.534G>A p.M178I | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs775084835, COSV69969834; called by mutect2, varscan2
- SLC35F3 | c.401G>A p.R134K (on ENST00000366617 / NM_001300845.1; = p.R203K on NM_173508.4) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV64020965; called by muse, mutect2, varscan2
- SLC39A5 | c.247G>A p.G83R | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.448); catalogued as rs777465518, COSV57192959; called by muse, mutect2, varscan2
- SLC4A2 | c.2552C>T p.P851L | Missense Mutation (SNP) | VAF 42/85 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99879427; called by muse, mutect2, varscan2
- SLC6A5 | c.964G>A p.D322N | Missense Mutation (SNP) | VAF 63/119 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV54226280, COSV54230408; called by muse, mutect2, varscan2
- SMAD6 | c.1412G>A p.G471D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56596784; called by muse, mutect2, varscan2
- SPACA1 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV52759235; called by mutect2, varscan2
- SPATA31D1 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV61199208; called by mutect2, varscan2
- SPEN | c.9757C>A p.P3253T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (1); PolyPhen probably damaging (0.981); catalogued as COSV65361926, COSV65365824; called by muse, mutect2, varscan2
- SPRY1 | c.463C>T p.R155W | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs780874264, COSV59338923; called by muse, mutect2, varscan2
- SPZ1 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV57064356; called by muse, mutect2
- SSTR4 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs1283805258, COSV54797504, COSV54799401; called by muse, mutect2, varscan2
- STK36 | c.1481C>T p.S494F | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.1); catalogued as rs1243212570, COSV55329183; called by muse, mutect2, varscan2
- STYXL2 | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV54808413; called by muse, mutect2, varscan2
- STYXL2 | c.2711C>T p.S904F | Missense Mutation (SNP) | VAF 41/74 reads (55%) | SIFT tolerated (0.49); PolyPhen benign (0.022); catalogued as rs898398838, COSV54801751; called by muse, varscan2
- SYCP2L | c.1190C>T p.S397F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV51652618; called by muse, mutect2, varscan2
- SYNPO2L | c.1687G>A p.G563R (on ENST00000394810 / NM_001114133.3; = p.G339R on NM_024875.5) | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65738408; called by muse, mutect2, varscan2
- TACC2 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 52/61 reads (85%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as rs757642911, COSV57751654; called by muse, mutect2, varscan2
- TACC2 | c.8644G>A p.E2882K (on ENST00000334433; = p.E960K on NM_006997.4) | Missense Mutation (SNP) | VAF 22/23 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53286934; called by muse, mutect2, varscan2
- TAF1L | c.5417G>A p.R1806K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.231); catalogued as COSV54265834, COSV54266320; called by muse, mutect2, varscan2
- TAF1L | c.4204G>A p.V1402M | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV54266334; called by muse, mutect2, varscan2
- TAF1L | c.1906C>T p.R636C | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144278499; called by mutect2, varscan2
- TBR1 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.835); catalogued as COSV67418799; called by muse, mutect2, varscan2
- TC2N | c.178G>A p.D60N | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV61747810; called by muse, mutect2, varscan2
- TEX15 | c.6970G>A p.E2324K (on ENST00000256246; = p.E2707K on NM_001350162.2) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.103); catalogued as rs541424857, COSV56350833; called by muse, mutect2, varscan2
- THSD7B | c.914C>T p.S305L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.025); catalogued as rs866588841, COSV55651332; called by mutect2, varscan2
- TMEM132B | c.3145G>A p.D1049N | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs924808831, COSV54748040; called by muse, mutect2, varscan2
- TMEM135 | c.1270C>T p.L424F | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59700193; called by muse, mutect2, varscan2
- TMEM184A | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.458); catalogued as rs762642921, COSV52475068; called by mutect2, varscan2
- TMEM184B | c.403G>A p.G135R | Missense Mutation (SNP) | VAF 97/118 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV62673526; called by muse, mutect2, varscan2
- TNXB | c.6113C>T p.S2038F (on ENST00000647633; = p.S1791F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 620/830 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64485366; called by muse, mutect2, varscan2
- TOX3 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as COSV54871149; called by muse, mutect2, varscan2
- TP73 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60704694; called by muse, mutect2, varscan2
- TPX2 | c.1372C>T p.H458Y | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55917910, COSV55918947; called by mutect2, varscan2
- TRAPPC10 | c.2291C>T p.S764F | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as COSV52380123; called by muse, varscan2
- TRGC1 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1482950269; called by muse, mutect2, varscan2
- TRHDE | c.1811G>A p.G604E | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT tolerated (0.97); PolyPhen benign (0.065); catalogued as rs866156965, COSV53857820; called by muse, mutect2, varscan2
- TRIM42 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs200931245, COSV53880493; called by mutect2, varscan2
- TRIM58 | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1417587813, COSV63571605; called by mutect2, varscan2
- TRIM67 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 48/106 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64159703; called by muse, mutect2, varscan2
- TRMT2B | c.622T>C p.F208L | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT deleterious (0.04); PolyPhen benign (0.201); catalogued as COSV58620508; called by muse, mutect2, varscan2
- TRPM5 | c.2357G>A p.G786D | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV50170930; called by muse, mutect2, varscan2
- TRPM6 | c.4308G>A p.M1436I | Missense Mutation (SNP) | VAF 23/39 reads (59%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV62509321; called by muse, mutect2, varscan2
- TRPM6 | c.1134+2T>G p.X378_splice | Splice Site (SNP) | VAF 19/34 reads (56%) | catalogued as COSV62518705; called by muse, mutect2, varscan2
- TRPM6 | c.485G>C p.G162A | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62518717; called by muse, mutect2, varscan2
- TRPV5 | c.1320G>A p.M440I | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.561); catalogued as COSV54688483; called by muse, mutect2, varscan2
- TSHZ2 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.996); catalogued as COSV61587181; called by muse, mutect2, varscan2
- TTN | c.72316G>A p.E24106K (on ENST00000591111; = p.E16682K on NM_003319.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | PolyPhen benign (0.167); catalogued as COSV60239905; called by muse, varscan2
- TTN | c.40916C>T p.S13639F (on ENST00000591111; = p.S6215F on NM_003319.4) | Missense Mutation (SNP) | VAF 18/32 reads (56%) | PolyPhen possibly damaging (0.483); catalogued as rs763279178, COSV59895966; called by muse, mutect2, varscan2
- TTN | c.39521G>A p.G13174E (on ENST00000591111; = p.G5750E on NM_003319.4) | Missense Mutation (SNP) | VAF 7/21 reads (33%) | PolyPhen probably damaging (0.959); catalogued as rs1157011423, COSV60041104, COSV60280736; called by muse, mutect2, varscan2
- TTN | c.22825G>A p.G7609R (on ENST00000591111; = p.G6682R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/17 reads (47%) | PolyPhen probably damaging (0.925); catalogued as rs1462977201, COSV60239990; called by muse, mutect2, varscan2
- TTN | c.9839C>T p.S3280F (on ENST00000591111; = p.S3234F on NM_003319.4) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | PolyPhen probably damaging (0.961); catalogued as rs747768723, COSV60240000; called by muse, mutect2, varscan2
- TUBGCP5 | c.1726G>A p.E576K | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as rs778607686; called by muse, mutect2, varscan2
- UBE2O | c.1629-1G>A p.X543_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV100083938; called by muse, mutect2, varscan2
- UMOD | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV56774663; called by muse, mutect2, varscan2
- UPF1 | c.2221C>T p.R741C (on ENST00000599848 / NM_001297549.2; = p.R730C on NM_002911.4) | Missense Mutation (SNP) | VAF 186/287 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1195464113, COSV53199917; called by muse, mutect2, varscan2
- USH2A | c.8725G>A p.G2909S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs758347918, COSV100229215, COSV56410669; called by muse, mutect2, varscan2
- VARS1 | c.2617C>T p.P873S | Missense Mutation (SNP) | VAF 113/625 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63304974; called by muse, mutect2, varscan2
- VAV3 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs774815323, COSV58388865; called by mutect2, varscan2
- VCAN | c.4378G>A p.E1460K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.071); catalogued as COSV54102865; called by mutect2, varscan2
- VTN | c.614C>A p.P205H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99879362; called by mutect2, varscan2
- WFDC12 | c.288G>A p.W96* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs1000800677, COSV65661268; called by muse, mutect2, varscan2
- WNK4 | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV53821648; called by muse, mutect2, varscan2
- WSCD2 | c.512G>A p.G171D | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as COSV54588220; called by muse, mutect2, varscan2
- XIRP1 | c.905C>T p.P302L | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV61140133; called by muse, mutect2, varscan2
- XKR4 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59332084; called by muse, varscan2
- YTHDF1 | c.370C>T p.P124S | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV64833635; called by muse, mutect2, varscan2
- ZAN | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 108/262 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs368072574, COSV61804642; called by muse, mutect2, varscan2
- ZC3HAV1L | c.587C>T p.S196F | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.568); catalogued as rs778114236, COSV51964269, COSV51964961; called by muse, mutect2, varscan2
- ZDHHC1 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.986); catalogued as COSV62215575; called by muse, varscan2
- ZNF157 | c.443G>A p.G148D | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs1193989413, COSV65659434; called by muse, mutect2, varscan2
- ZNF17 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV56922116; called by muse, mutect2, varscan2
- ZNF254 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.095); catalogued as COSV61644088; called by muse, mutect2, varscan2
- ZNF318 | c.1364C>T p.P455L | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV58935937; called by muse, mutect2, varscan2
- ZNF480 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV57997556; called by muse, mutect2, varscan2
- ZNF572 | c.1510C>T p.P504S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.003); catalogued as rs867474462, COSV60001356; called by muse, mutect2, varscan2
- ZNF648 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as rs757852320, COSV60569859; called by mutect2, varscan2
- ZNF705A | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100828255; called by muse, mutect2, varscan2
- ZNF813 | c.948A>C p.R316S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0.2); catalogued as COSV67177530; called by muse, mutect2, varscan2
- ZNF99 | c.1366G>A p.E456K | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.325); catalogued as COSV68056242; called by mutect2, varscan2
- ZNFX1 | c.3202C>T p.R1068C | Missense Mutation (SNP) | VAF 53/131 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.33); catalogued as rs762048451, COSV65577846; called by muse, mutect2, varscan2
- ARID1A | c.5634dup p.R1879Sfs*22 | Frame Shift Ins (INS) | VAF 56/131 reads (43%) | called by mutect2, pindel, varscan2
- ASAH2 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 24/30 reads (80%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CCNG1 | c.185_186dup p.T63* | Frame Shift Ins (INS) | VAF 24/86 reads (28%) | called by pindel, varscan2
- GOLGA6L22 | c.130G>A p.G44S | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PCLO | c.10610C>T p.P3537L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.221); called by muse, mutect2
- RBP3 | c.2996A>C p.K999T | Missense Mutation (SNP) | VAF 70/79 reads (89%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.843); called by muse, varscan2
- TCAF2 | c.2485G>A p.A829T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TRAV20 | c.23C>A p.A8E | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- A2ML1 | c.1383C>T p.P461= | Silent (SNP) | VAF 48/62 reads (77%) | catalogued as COSV100228353; called by muse, varscan2
- AADACL3 | c.1023C>T p.I341= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs189878282, COSV60199968; called by muse, mutect2, varscan2
- ABCA6 | c.3810C>T p.I1270= | Silent (SNP) | VAF 35/120 reads (29%) | catalogued as COSV52642514, COSV52647034; called by muse, mutect2, varscan2
- ACOT11 | c.1128C>T p.S376= | Silent (SNP) | VAF 33/112 reads (29%) | catalogued as rs745659196, COSV59350660; called by muse, mutect2, varscan2
- ACTN1 | c.2139C>T p.I713= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV51995510; called by muse, mutect2, varscan2
- ACTN2 | c.186C>T p.I62= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as rs34403480, COSV63977506; ClinVar: likely benign; called by mutect2, varscan2
- ACTRT2 | c.715C>T p.L239= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV65760078; called by muse, mutect2, varscan2
- ADAM28 | c.1956C>T p.I652= | Silent (SNP) | VAF 11/18 reads (61%) | catalogued as rs777423480, COSV56097541; called by muse, mutect2, varscan2
- ADCY3 | c.99C>T p.G33= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as COSV53170824; called by muse, mutect2, varscan2
- ADGRF1 | c.933C>T p.F311= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as rs1383579171, COSV51946481; called by mutect2, varscan2
- AKAP17A | c.421C>T p.L141= | Silent (SNP) | VAF 81/102 reads (79%) | catalogued as COSV58311246; called by muse, mutect2, varscan2
- AKAP3 | c.1584C>T p.I528= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1371126949, COSV57417343; called by mutect2, varscan2
- AKAP4 | c.621C>T p.S207= | Silent (SNP) | VAF 48/57 reads (84%) | catalogued as COSV62075180; called by muse, mutect2, varscan2
- AKR1B10 | c.270G>A p.R90= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs1376877628, COSV62056166; called by muse, mutect2, varscan2
- ALLC | c.195G>A p.R65= | Silent (SNP) | VAF 59/146 reads (40%) | catalogued as COSV52993587, COSV52997182; called by muse, mutect2, varscan2
- ANAPC4 | c.2292C>T p.A764= | Silent (SNP) | VAF 32/39 reads (82%) | catalogued as COSV59545582; called by muse, mutect2, varscan2
- ANK3 | c.13086G>A p.V4362= (on ENST00000280772 / NM_001320874.2; = p.V986= on NM_001149.3) | Silent (SNP) | VAF 49/57 reads (86%) | catalogued as rs768776250, COSV55073254; ClinVar: uncertain significance; called by mutect2, varscan2
- ANKRD45 | c.570G>A p.G190= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as rs1336295515, COSV60960021; called by muse, mutect2, varscan2
- ANKRD7 | c.165G>A p.Q55= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as COSV54556034; called by muse, mutect2, varscan2
- ARPP21 | c.2367C>T p.V789= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV51804337; called by muse, mutect2
- ASAP3 | c.777G>A p.Q259= | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as COSV60876985; called by muse, mutect2, varscan2
- ATP8B4 | c.2925G>A p.G975= | Silent (SNP) | VAF 8/10 reads (80%) | catalogued as rs1295811155, COSV52721293; called by muse, mutect2, varscan2
- B3GNT4 | c.528G>A p.R176= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV57337103; called by muse, mutect2, varscan2
- BCR | c.3234C>T p.I1078= | Silent (SNP) | VAF 11/13 reads (85%) | catalogued as rs148447062, COSV59934300; called by mutect2, varscan2
- BPI | c.1392C>T p.V464= (on ENST00000262865; = p.V460= on NM_001725.3) | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV53407376; called by muse, varscan2
- BSN | c.2796G>A p.K932= | Silent (SNP) | VAF 41/75 reads (55%) | catalogued as rs771291530, COSV56524326, COSV99607058; called by muse, mutect2, varscan2
- C10orf71 | c.528C>T p.F176= | Silent (SNP) | VAF 17/22 reads (77%) | catalogued as rs768871388, COSV60510795; called by mutect2, varscan2
- C1orf94 | c.729C>T p.F243= (on ENST00000488417 / NM_001134734.2; = p.F53= on NM_032884.5) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs867717167, COSV64914875; called by muse, mutect2
- C2CD4A | c.48G>A p.R16= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as COSV62789139; called by muse, mutect2, varscan2
- CACNA1S | c.2538G>A p.E846= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as COSV62942270; called by muse, mutect2, varscan2
- CAPRIN1 | c.1896C>T p.F632= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV58221569; called by mutect2, varscan2
- CCL25 | c.219G>A p.K73= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs1461424937, COSV53664794; called by muse, mutect2
- CCRL2 | c.27G>A p.E9= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV62193939; called by muse, mutect2, varscan2
- CD3D | c.81G>A p.E27= | Silent (SNP) | VAF 14/17 reads (82%) | catalogued as rs144504840; called by muse, mutect2, varscan2
- CDH26 | c.654C>T p.F218= | Silent (SNP) | VAF 55/143 reads (38%) | catalogued as COSV54851599; called by muse, mutect2, varscan2
- CERKL | c.1608C>T p.V536= (on ENST00000339098 / NM_001030311.2; = p.V510= on NM_201548.5) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV59211536; called by muse, mutect2, varscan2
- CERKL | c.297C>T p.F99= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV59211554; called by muse, mutect2, varscan2
- CFAP46 | c.7209C>T p.I2403= | Silent (SNP) | VAF 19/23 reads (83%) | catalogued as rs758726257, COSV54154022; called by muse, mutect2, varscan2
- CFAP61 | c.2616C>T p.S872= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as COSV55640943; called by muse, mutect2, varscan2
- CFL1 | c.480C>T p.S160= | Silent (SNP) | VAF 46/69 reads (67%) | catalogued as rs760995765, COSV57450242; called by muse, mutect2, varscan2
- CHRNA2 | c.495C>T p.L165= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as rs1341670445, COSV53559069; called by muse, mutect2, varscan2
- CHST12 | c.549C>T p.I183= | Silent (SNP) | VAF 29/70 reads (41%) | catalogued as rs150939856; called by mutect2, varscan2
- CLDN14 | c.198C>T p.I66= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV59776362; called by muse, varscan2
- CMPK2 | c.687T>C p.F229= | Silent (SNP) | VAF 41/101 reads (41%) | catalogued as COSV56775711; called by muse, mutect2, varscan2
- CMYA5 | c.10143G>A p.E3381= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as COSV71406488; called by muse, mutect2, varscan2
- CNTNAP5 | c.657C>T p.F219= | Silent (SNP) | VAF 12/22 reads (55%) | catalogued as COSV101443772, COSV70502003; called by muse, mutect2, varscan2
- COBL | c.2707C>T p.L903= | Silent (SNP) | VAF 49/94 reads (52%) | catalogued as COSV54353843; called by muse, mutect2, varscan2
- COL10A1 | c.1023G>A p.G341= | Silent (SNP) | VAF 16/32 reads (50%) | catalogued as rs548995634, COSV54574038; called by muse, mutect2, varscan2
- COL15A1 | c.2118G>A p.G706= | Silent (SNP) | VAF 10/23 reads (43%) | catalogued as COSV66640926; called by muse, mutect2, varscan2
- COL7A1 | c.372C>T p.L124= | Silent (SNP) | VAF 49/101 reads (49%) | catalogued as COSV60391019, COSV60400193; called by muse, mutect2, varscan2
- CP | c.2013G>A p.R671= | Silent (SNP) | VAF 28/60 reads (47%) | catalogued as rs755014066, COSV52832742; called by muse, mutect2, varscan2
- CTNNA2 | c.1347G>A p.R449= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as COSV58169300; called by muse, mutect2, varscan2
- CX3CR1 | c.927G>A p.G309= | Silent (SNP) | VAF 54/119 reads (45%) | catalogued as COSV64192906, COSV64194532; called by muse, mutect2, varscan2
- CYFIP2 | c.789C>T p.L263= | Silent (SNP) | VAF 43/173 reads (25%) | catalogued as COSV59046744; called by muse, mutect2, varscan2
- CYP26A1 | c.1252C>A p.R418= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as rs984252420, COSV56417599; called by muse, mutect2
- DBH | c.1209G>A p.G403= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV67549724; called by muse, mutect2, varscan2
- DCANP1 | c.714G>A p.R238= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as rs756086139, COSV72345885; called by muse, mutect2, varscan2
- DKK4 | c.12C>T p.A4= | Silent (SNP) | VAF 9/16 reads (56%) | catalogued as rs770378273, COSV55183268; called by muse, mutect2, varscan2
- DMRTA2 | c.768C>T p.S256= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV101288810; called by mutect2, varscan2
- DNAH7 | c.9543G>A p.E3181= | Silent (SNP) | VAF 36/80 reads (45%) | catalogued as COSV56777564; called by muse, mutect2, varscan2
- DOCK4 | c.2656C>T p.L886= | Silent (SNP) | VAF 20/51 reads (39%) | catalogued as COSV70241177; called by muse, mutect2, varscan2
- DUSP21 | c.69C>T p.S23= | Silent (SNP) | VAF 55/69 reads (80%) | catalogued as COSV59134640; called by muse, mutect2, varscan2
- DYNC1H1 | c.339C>T p.S113= | Silent (SNP) | VAF 42/104 reads (40%) | catalogued as COSV64140293; called by muse, varscan2
- DYNC1H1 | c.12165C>T p.V4055= | Silent (SNP) | VAF 22/62 reads (35%) | catalogued as rs753386602, COSV64140296; called by mutect2, varscan2
- EDEM2 | c.501C>T p.T167= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs750047372, COSV65713319; called by muse, mutect2, varscan2
- EGFLAM | c.2331C>G p.S777= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV59312123; called by muse, mutect2, varscan2
- EPHB1 | c.372G>A p.K124= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV67660899, COSV67667577; called by muse, mutect2, varscan2
- EVPL | c.1026C>G p.A342= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV56911345, COSV56914156; called by muse, mutect2, varscan2
- F10 | c.1296C>T p.F432= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs139031355, COSV65021884; called by mutect2, varscan2
- FAM71A | c.198C>T p.V66= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as COSV54237144; called by muse, mutect2, varscan2
- FBLN7 | c.768C>A p.P256= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV99734662; called by muse, mutect2, varscan2
- FBXL7 | c.1062C>T p.Y354= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV61650304; called by muse, mutect2, varscan2
- FBXW8 | c.426C>T p.F142= (on ENST00000309909; = p.F180= on NM_012174.1) | Silent (SNP) | VAF 36/84 reads (43%) | catalogued as COSV59302098; called by muse, mutect2, varscan2
- FCER2 | c.531C>T p.F177= | Silent (SNP) | VAF 24/93 reads (26%) | catalogued as rs536515427, COSV60915956, COSV60916707; called by muse, mutect2, varscan2
- FCGR3A | c.564C>T p.I188= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as COSV63460250; called by mutect2, varscan2
- FGD2 | c.1497G>A p.L499= | Silent (SNP) | VAF 50/130 reads (38%) | catalogued as COSV51465319; called by mutect2, varscan2
- FLG | c.11706C>T p.P3902= | Silent (SNP) | VAF 22/39 reads (56%) | catalogued as rs147335121; called by muse, mutect2, varscan2
- FOSL2 | c.840C>T p.L280= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs200360785, COSV53104679; called by muse, mutect2, varscan2
- FRMD7 | c.1485C>T p.V495= | Silent (SNP) | VAF 20/24 reads (83%) | catalogued as COSV53748024; called by muse, mutect2, varscan2
- GDAP1 | c.102C>T p.S34= | Silent (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- GFRA3 | c.798G>T p.V266= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV51230273; called by mutect2, varscan2
- GJA8 | c.837C>T p.F279= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs782541622, COSV53789985; called by muse, mutect2, varscan2
- GLP2R | c.1068C>T p.F356= | Silent (SNP) | VAF 98/280 reads (35%) | catalogued as COSV52327875; called by mutect2, varscan2
- GNAZ | c.804C>T p.F268= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as COSV50743511; called by muse, mutect2, varscan2
- GNAZ | c.805C>T p.L269= | Silent (SNP) | VAF 36/41 reads (88%) | catalogued as COSV99320292; called by muse, mutect2, varscan2
- GPR31 | c.90G>A p.L30= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as COSV100834091; called by mutect2, varscan2
- GRB14 | c.534G>A p.G178= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs963196285, COSV55738396; called by muse, mutect2, varscan2
- GRK7 | c.498C>T p.F166= | Silent (SNP) | VAF 67/155 reads (43%) | catalogued as rs780812559, COSV53821926; called by muse, mutect2, varscan2
- GUCY1A2 | c.2178C>T p.F726= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as COSV56492172; called by muse, mutect2, varscan2
- GUSB | c.1440C>T p.T480= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as COSV59223015; called by muse, mutect2, varscan2
- H6PD | c.1953C>T p.I651= | Silent (SNP) | VAF 52/95 reads (55%) | catalogued as COSV66231855; called by muse, mutect2, varscan2
- HAS1 | c.552G>A p.R184= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV55788929; called by muse, mutect2, varscan2
- HGD | c.1080G>A p.G360= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs752713602, COSV52200068; ClinVar: likely benign; called by muse, mutect2, varscan2
- HSPG2 | c.858G>A p.G286= | Silent (SNP) | VAF 30/78 reads (38%) | catalogued as COSV65930674; called by muse, mutect2, varscan2
- HTR1E | c.429C>T p.I143= | Silent (SNP) | VAF 23/51 reads (45%) | catalogued as rs1240617309, COSV59509356, COSV59509739; called by muse, mutect2, varscan2
- IFI6 | c.357C>T p.T119= | Silent (SNP) | VAF 40/77 reads (52%) | catalogued as COSV59269880; called by muse, mutect2, varscan2
- IFNA16 | c.177C>T p.F59= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as rs750764392, COSV66509773; called by muse, mutect2, varscan2
- IGKV1-8 | c.273C>T p.F91= | Silent (SNP) | VAF 25/56 reads (45%) | called by mutect2, varscan2
- IGSF5 | c.582C>T p.S194= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs199978079, COSV66031061; called by mutect2, varscan2
- IKZF4 | c.939C>T p.I313= | Silent (SNP) | VAF 42/107 reads (39%) | catalogued as rs780736271, COSV56270386; called by mutect2, varscan2
- INTS11 | c.1476G>A p.L492= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100027836; called by muse, varscan2
- ITGA6 | c.1953C>T p.P651= (on ENST00000442250; = p.P612= on NM_000210.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as COSV51242972; called by muse, mutect2, varscan2
- ITLN2 | c.789T>C p.C263= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as COSV63538076; called by muse, mutect2, varscan2
- KCNJ14 | c.1186C>T p.L396= | Silent (SNP) | VAF 55/97 reads (57%) | catalogued as COSV57309796, COSV57310285; called by muse, mutect2, varscan2
- KCNJ15 | c.21C>T p.G7= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV60811608; called by muse, mutect2, varscan2
- KCNN3 | c.973C>T p.L325= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as COSV55223318; called by muse, mutect2, varscan2
- KIR3DL3 | c.78G>A p.Q26= | Silent (SNP) | VAF 126/274 reads (46%) | catalogued as rs1320982837; called by muse, varscan2
- KTN1 | c.216C>T p.L72= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as COSV68024925; called by muse, mutect2, varscan2
- LAMB4 | c.4443C>T p.F1481= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV52726563; called by mutect2, varscan2
- LEO1 | c.558G>A p.Q186= | Silent (SNP) | VAF 108/279 reads (39%) | catalogued as COSV55176880; called by muse, mutect2, varscan2
- LETM1 | c.531C>T p.I177= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs750791474, COSV57103248; called by mutect2, varscan2
- LLGL2 | c.93C>T p.F31= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as rs762924049, COSV51384463; called by muse, mutect2, varscan2
- LRP1 | c.7242C>T p.I2414= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV54520427; called by muse, mutect2, varscan2
- LRRC55 | c.618C>T p.P206= | Silent (SNP) | VAF 43/104 reads (41%) | catalogued as rs375438825; called by muse, mutect2, varscan2
- LY75 | c.1044G>A p.V348= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV55110791; called by muse, mutect2, varscan2
- MAP3K9 | c.1438C>T p.L480= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV67122405; called by muse, varscan2
- MAPK13 | c.438C>T p.V146= | Silent (SNP) | VAF 42/198 reads (21%) | catalogued as rs771949520, COSV52984294; called by muse, mutect2, varscan2
- MATN3 | c.666G>A p.V222= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1297090342, COSV68100435; called by muse, mutect2, varscan2
- MCTP2 | c.2619G>A p.K873= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as COSV63296170; called by muse, mutect2, varscan2
- MINAR1 | c.1848C>T p.V616= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV59585331; called by muse, mutect2, varscan2
- MOV10 | c.2259C>T p.A753= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as COSV53518838; called by muse, mutect2, varscan2
- MPND | c.1311C>T p.T437= | Silent (SNP) | VAF 35/119 reads (29%) | catalogued as COSV53658941, COSV99515216; called by muse, mutect2, varscan2
- MROH2B | c.4116C>T p.I1372= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs1239749104, COSV68180975; called by muse, mutect2, varscan2
- MROH2B | c.264C>T p.F88= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs372417503; called by mutect2, varscan2
- MUC15 | c.891G>A p.G297= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV55556309, COSV99846503; called by muse, mutect2, varscan2
- MYO7A | c.2103C>T p.L701= | Silent (SNP) | VAF 47/204 reads (23%) | catalogued as rs1555079443, COSV68686282; called by muse, mutect2, varscan2
- MYOM2 | c.2292C>T p.P764= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100036270; called by mutect2, varscan2
- NDRG3 | c.711C>T p.I237= (on ENST00000349004 / NM_032013.4; = p.I225= on NM_022477.4) | Silent (SNP) | VAF 108/234 reads (46%) | catalogued as rs551914837, COSV62422943; called by muse, mutect2, varscan2
- NDUFAF4 | c.270G>A p.P90= | Silent (SNP) | VAF 41/79 reads (52%) | catalogued as rs372832376; ClinVar: likely benign / uncertain significance; called by mutect2, varscan2
- NEBL | c.2388C>T p.G796= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV65804857; called by muse, mutect2, varscan2
- NID1 | c.996C>T p.L332= | Silent (SNP) | VAF 33/67 reads (49%) | catalogued as COSV51625747; called by muse, mutect2, varscan2
- NID2 | c.2154C>T p.F718= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs760359263, COSV53498902; called by muse, mutect2, varscan2
- NLRP12 | c.2931G>A p.L977= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV60751927; called by muse, mutect2, varscan2
- NLRP13 | c.2862G>A p.V954= | Silent (SNP) | VAF 23/55 reads (42%) | catalogued as COSV61623459; called by mutect2, varscan2
- NLRP8 | c.2872C>T p.L958= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as COSV52591669; called by muse, mutect2, varscan2
- NPAS1 | c.477C>T p.F159= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as rs866230329, COSV71384065, COSV71384074; called by muse, mutect2, varscan2
- NTNG1 | c.816G>A p.G272= | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as COSV53982436; called by muse, mutect2, varscan2
- NUP210 | c.4125C>T p.S1375= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as rs1404901817, COSV54410887; called by muse, varscan2
- NUTF2 | c.138C>T p.F46= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as rs755127384, COSV54647013; called by muse, mutect2, varscan2
- OR1F1 | c.420C>T p.L140= | Silent (SNP) | VAF 37/96 reads (39%) | catalogued as COSV58961908; called by muse, mutect2, varscan2
- OR1Q1 | c.189C>T p.L63= | Silent (SNP) | VAF 36/76 reads (47%) | catalogued as rs1406331115, COSV52918707; called by muse, mutect2, varscan2
- OR2A14 | c.456C>T p.F152= | Silent (SNP) | VAF 64/153 reads (42%) | catalogued as COSV68718394; called by muse, mutect2, varscan2
- OR2L13 | c.816C>T p.I272= | Silent (SNP) | VAF 27/60 reads (45%) | catalogued as COSV100813695, COSV63552030; called by muse, mutect2, varscan2
- OR2T8 | c.177C>T p.F59= | Silent (SNP) | VAF 44/179 reads (25%) | catalogued as COSV60664039; called by muse, varscan2
- OR4X2 | c.105C>T p.F35= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs759467119, COSV56582630; called by muse, mutect2, varscan2
- OR51D1 | c.945C>T p.V315= | Silent (SNP) | VAF 19/24 reads (79%) | catalogued as rs1268465023, COSV62914642; called by muse, mutect2, varscan2
- OR7G1 | c.402C>T p.V134= | Silent (SNP) | VAF 47/159 reads (30%) | catalogued as COSV53318465; called by muse, mutect2, varscan2
- OR9Q1 | c.666C>T p.I222= | Silent (SNP) | VAF 10/24 reads (42%) | catalogued as rs139135884, COSV59038731, COSV59040427; called by mutect2, varscan2
- PCNX2 | c.5769C>T p.S1923= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV50846255; called by muse, mutect2, varscan2
- PDZD2 | c.4452G>A p.R1484= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs1236476073, COSV56867628; called by muse, mutect2, varscan2
- PI4K2B | c.1173T>C p.F391= | Silent (SNP) | VAF 20/22 reads (91%) | catalogued as rs1372833883, COSV53512472; called by muse, mutect2, varscan2
- PKHD1L1 | c.10929G>A p.V3643= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV101005024; called by mutect2, varscan2
- PKP2 | c.1554C>T p.L518= | Silent (SNP) | VAF 69/141 reads (49%) | catalogued as COSV50740693; called by muse, mutect2, varscan2
- PLA2R1 | c.1032G>A p.R344= | Silent (SNP) | VAF 43/107 reads (40%) | catalogued as COSV51783873; called by muse, mutect2, varscan2
- PLEKHF1 | c.450C>T p.I150= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV71410290; called by muse, varscan2
- PLEKHH2 | c.2661C>T p.I887= | Silent (SNP) | VAF 118/254 reads (46%) | catalogued as rs139893812; called by muse, mutect2, varscan2
- PM20D1 | c.552C>T p.F184= | Silent (SNP) | VAF 33/59 reads (56%) | catalogued as COSV65649397; called by muse, mutect2, varscan2
- PNN | c.1179T>C p.V393= | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as COSV53767727; called by muse, mutect2, varscan2
- POGZ | c.2172T>A p.P724= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV55039973; called by mutect2, varscan2
- PRAMEF20 | c.1182G>A p.L394= | Silent (SNP) | VAF 294/524 reads (56%) | called by muse, mutect2, varscan2
- PRLHR | c.12G>A p.S4= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs867151973, COSV53304059; called by mutect2, varscan2
- PRSS38 | c.945C>T p.V315= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs766085098, COSV64541314; called by muse, mutect2, varscan2
- PTCH1 | c.4179C>T p.P1393= | Silent (SNP) | VAF 47/95 reads (49%) | catalogued as COSV59487131; called by muse, mutect2, varscan2
- RABL2A | c.315G>A p.R105= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as COSV64573365; called by muse, mutect2, varscan2
- RABL2A | c.471C>T p.F157= | Silent (SNP) | VAF 45/109 reads (41%) | catalogued as rs774414165, COSV64572814; called by mutect2, varscan2
- RGS7BP | c.15G>A p.P5= | Silent (SNP) | VAF 12/26 reads (46%) | catalogued as COSV61833788; called by mutect2, varscan2
- RHOH | c.408G>A p.G136= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as rs368977127; called by muse, mutect2, varscan2
- RIC3 | c.399C>T p.A133= | Silent (SNP) | VAF 69/165 reads (42%) | catalogued as COSV58303754; called by muse, mutect2, varscan2
- ROS1 | c.6909G>A p.R2303= | Silent (SNP) | VAF 14/28 reads (50%) | catalogued as COSV63859499; called by muse, mutect2, varscan2
- RPL6 | c.303C>T p.N101= | Silent (SNP) | VAF 72/142 reads (51%) | catalogued as rs760501485, COSV52517675; called by mutect2, varscan2
- SATB2 | c.1005C>T p.I335= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV53490188; called by mutect2, varscan2
- SBF2 | c.1536C>T p.N512= | Silent (SNP) | VAF 85/179 reads (47%) | catalogued as COSV56306628, COSV99814724; called by muse, mutect2, varscan2
- SCN1A | c.2643G>A p.K881= (on ENST00000303395 / NM_001202435.3; = p.K870= on NM_006920.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as COSV57681101; called by muse, mutect2, varscan2
- SDK2 | c.5028G>A p.K1676= | Silent (SNP) | VAF 21/35 reads (60%) | catalogued as COSV66192919; called by muse, mutect2, varscan2
- SEC61A1 | c.993C>T p.G331= | Silent (SNP) | VAF 49/132 reads (37%) | catalogued as COSV54578212; called by muse, mutect2, varscan2
- SERPING1 | c.345C>G p.T115= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV99557734; called by muse, varscan2
- SHD | c.807C>T p.T269= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV56668197; called by muse, mutect2, varscan2
- SLC16A14 | c.1059C>T p.F353= | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as COSV54620369; called by muse, mutect2, varscan2
- SLC26A8 | c.378C>T p.I126= | Silent (SNP) | VAF 159/410 reads (39%) | catalogued as rs142275991; called by muse, varscan2
- SLC4A2 | c.2553C>T p.P851= | Silent (SNP) | VAF 39/81 reads (48%) | catalogued as COSV99879428; called by muse, mutect2, varscan2
- SMPD3 | c.1371C>T p.I457= | Silent (SNP) | VAF 21/54 reads (39%) | catalogued as rs760930521, COSV54714477; called by mutect2, varscan2
- SNX29 | c.1119C>T p.P373= | Silent (SNP) | VAF 16/36 reads (44%) | catalogued as rs770138155, COSV100026771, COSV100030121; called by muse, mutect2, varscan2
- SPATC1 | c.1359G>A p.L453= | Silent (SNP) | VAF 13/21 reads (62%) | catalogued as COSV66299566; called by muse, mutect2, varscan2
- SPEM2 | c.987C>T p.S329= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV100424065; called by muse, mutect2, varscan2
- SPHKAP | c.2946G>A p.K982= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV60889604; called by muse, mutect2, varscan2
- SPOCK2 | c.846C>T p.I282= | Silent (SNP) | VAF 82/94 reads (87%) | catalogued as rs768468812, COSV58037775; called by muse, varscan2
- STAB1 | c.954C>T p.F318= | Silent (SNP) | VAF 32/62 reads (52%) | catalogued as rs373264845; called by mutect2, varscan2
- SUPT5H | c.1650C>T p.I550= | Silent (SNP) | VAF 89/186 reads (48%) | catalogued as rs747736447, COSV63239134; called by muse, mutect2, varscan2
- SVEP1 | c.7734C>T p.I2578= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as COSV52841344; called by mutect2, varscan2
- SYAP1 | c.450C>T p.F150= | Silent (SNP) | VAF 66/80 reads (83%) | catalogued as COSV66468502; called by muse, mutect2, varscan2
- TEFM | c.948C>T p.F316= | Silent (SNP) | VAF 60/114 reads (53%) | catalogued as COSV58977328, COSV58977620; called by muse, mutect2, varscan2
- TENM3 | c.4167G>A p.V1389= | Silent (SNP) | VAF 13/13 reads (100%) | catalogued as COSV69315201; called by muse, mutect2, varscan2
- THEMIS | c.1002C>T p.I334= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as rs1393022141, COSV64073083; called by muse, mutect2, varscan2
- TMC7 | c.690C>T p.I230= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV58586033; called by mutect2, varscan2
- TMEM131 | c.3990C>T p.S1330= | Silent (SNP) | VAF 19/36 reads (53%) | catalogued as COSV51782882; called by muse, mutect2, varscan2
- TMEM59L | c.793C>T p.L265= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV53243082; called by muse, mutect2, varscan2
- TNFAIP2 | c.1734C>T p.L578= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV60695610; called by muse, mutect2, varscan2
- TRRAP | c.7287C>A p.T2429= (on ENST00000359863 / NM_001244580.1; = p.T2411= on NM_003496.3) | Silent (SNP) | VAF 31/70 reads (44%) | catalogued as COSV62851215; called by mutect2, varscan2
- TSPAN2 | c.246G>A p.R82= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV65690431; called by muse, mutect2, varscan2
- TTF1 | c.1737C>T p.I579= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as COSV57506353; called by mutect2, varscan2
- ULK4 | c.3630G>A p.K1210= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100089405; called by muse, mutect2, varscan2
- UNC13D | c.1662G>A p.E554= | Silent (SNP) | VAF 39/66 reads (59%) | catalogued as rs777053464, COSV52886471; called by muse, mutect2, varscan2
- VTN | c.615C>T p.P205= | Silent (SNP) | VAF 22/54 reads (41%) | catalogued as COSV56872322; called by mutect2, varscan2
- XDH | c.2058G>A p.V686= | Silent (SNP) | VAF 32/66 reads (48%) | catalogued as rs764631976, COSV65146976; called by mutect2, varscan2
- XKR4 | c.1392C>T p.I464= | Silent (SNP) | VAF 23/76 reads (30%) | catalogued as rs867658481, COSV59332092; called by muse, varscan2
- ZFHX4 | c.8346G>A p.E2782= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs1479736323, COSV51471031; called by muse, varscan2
- ZNF423 | c.1602C>T p.F534= (on ENST00000563137 / NM_001379286.1; = p.F526= on NM_015069.4) | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV52175278; called by muse, mutect2, varscan2
- ZNF831 | c.2511G>A p.E837= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV64043479; called by muse, mutect2, varscan2
- ZSCAN1 | c.1059G>A p.R353= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs765157294, COSV56607036; called by muse, mutect2, varscan2
- AC073310.1 | n.805C>T | RNA (SNP) | VAF 97/230 reads (42%) | called by muse, mutect2, varscan2
- C3P1 | n.2279T>C | RNA (SNP) | VAF 119/175 reads (68%) | catalogued as rs767198878; called by muse, mutect2, varscan2
- MCF2 | chrX:139646890 C>T | 5'Flank (SNP) | VAF 8/9 reads (89%) | catalogued as rs1392830585, COSV58491507; called by muse, mutect2, varscan2
- MIR200A | n.71G>A | RNA (SNP) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- MRPS17P9 | n.290G>A | RNA (SNP) | VAF 41/45 reads (91%) | called by muse, mutect2, varscan2
- NRG1 | c.502+31361C>T | Intron (SNP) | VAF 32/102 reads (31%) | catalogued as COSV55152326; called by mutect2, varscan2
- RIMS3 | c.-1C>T | 5'UTR (SNP) | VAF 16/36 reads (44%) | catalogued as COSV101013233; called by muse, mutect2
- SSPOP | n.14906G>A | RNA (SNP) | VAF 9/19 reads (47%) | catalogued as COSV65134562; called by muse, mutect2, varscan2
- SYTL2 | c.1459+1473C>T | Intron (SNP) | VAF 38/109 reads (35%) | catalogued as COSV100313480; called by muse, mutect2, varscan2
- TTN | c.10360+1174G>A | Intron (SNP) | VAF 12/31 reads (39%) | catalogued as rs1043880345, COSV100588329; called by muse, mutect2, varscan2
- TUBB7P | n.224C>T | RNA (SNP) | VAF 14/19 reads (74%) | catalogued as rs781878689; called by muse, mutect2, varscan2
- ZNF665 | c.-53-9137G>A | Intron (SNP) | VAF 62/124 reads (50%) | catalogued as COSV67216602; called by muse, mutect2, varscan2
